CCDI case PBBNKZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8d71c837-f6ad-48b5-9e90-1d2e07da2a2e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,615 days).

Biospecimens (2 samples)
- Sample 0DGB8Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGBAW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
